CGCI case BLGSP-71-19-00122 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7600ad9d-c4f6-4da8-88d9-52059e0ca8ee

Demographics
Sex at birth: female; Race: white; Age at index: 4 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 4.4 years (1,593 days); Year of diagnosis: 2002; Method of diagnosis: Incisional Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,950 days (13.6 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Bone marrow / Cerebrospinal fluid / Kidney, NOS.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Cervical, NOS; Tumor largest dimension diameter: 4 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 4,950 days (13.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 9469 [Blood test normal range upper: 920].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Weight: 15 kg; Height: 109 cm; BMI: 12.6.

Biospecimens (3 samples)
- Sample BLGSP-71-19-00122-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00122-09A.1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Sorted Cells; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Days to sample procurement: 5 days; Method of sample procurement: Aspirate; Tissue collection type: Retrospective.
- Sample BLGSP-71-19-00122-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 2,373 days (6.5 years); Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma, NOS; Extranodal site involvement: 3; Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical; Lymph node involvement site: para-aortic.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Cerebrospinal Fluid; Extranodal involvement site: Kidney.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 9469; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD3.
